Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEY, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAEY-01A (Primary Tumor).

Department of Pathology

ICD-O-3

Seminoma NOS 9061/3
Site: ® Testis NOS C62.9
JW 8/8/14

Direct dial

Mobile: -

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 3.2 cm; no angio-invasion present; no invasion in rete testis; pagetoid invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 9c010386-56dd-461e-975b-f8755c3f4247 (TCGA-2G-AAEY-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).